Somatic mutation profile of tumor specimen f6a7f764-2495-4a1d-89a2-e12f51 (aliquot f6a7f764-2495-4a1d-89a2-e12f51_D6_1) from CPTAC case 11CO054, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen f6a7f764-2495-4a1d-89a2-e12f51: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c3f7d0c-54d7-46c9-96ed-e3495971a66b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7de55254-1dfe-43e0-8ee9-6e26e8 (Blood Derived Normal), aliquot 7de55254-1dfe-43e0-8ee9-6e26e8_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d478e2b-dece-40e3-b1d3-e9079158c3f0

The open-access MAF lists 121 somatic variants for this specimen: 81 protein-altering or splice-affecting, 23 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 23, Intron 6, Nonsense Mutation 6, Splice Region 5, 3'UTR 4, Frame Shift Del 4, Frame Shift Ins 3, 5'Flank 2, RNA 2, 3'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 53/188 reads (28%) | catalogued as rs137854573, CM920034, COSV57321615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 111/430 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs770206447; called by muse, mutect2, varscan2
- AMZ1 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 76/607 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as rs376751656; called by muse, mutect2, varscan2
- ARHGAP6 | c.765G>T p.K255N | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV100272480, COSV57301527; called by muse, mutect2
- C20orf203 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 197/383 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.833); catalogued as rs1046928733, COSV62531558; called by muse, mutect2, varscan2
- CACNA2D1 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369215125; called by muse, mutect2, varscan2
- CCDC50 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 67/462 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs557807225, COSV66668580, COSV66669754; called by muse, mutect2, varscan2
- CENPC | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99893766; called by muse, mutect2, varscan2
- COL1A1 | c.3649C>T p.R1217W | Missense Mutation (SNP) | VAF 47/493 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763727068, COSV56802605; called by muse, mutect2
- CRTC3 | c.234G>A p.P78= | Splice Region (SNP) | VAF 12/72 reads (17%) | catalogued as rs370731406; called by muse, mutect2, varscan2
- DEPDC5 | c.2665G>A p.D889N (on ENST00000400246; = p.D958N on NM_014662.5) | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1223250924, COSV56700062; called by muse, varscan2
- E2F8 | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 49/386 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs369862489; called by muse, mutect2, varscan2
- FRAS1 | c.8357C>T p.A2786V | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as rs199895644; called by muse, mutect2, varscan2
- GALNT5 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs770726415; called by muse, mutect2
- GRID1 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs752715356, COSV100022404, COSV60016469, COSV60056647; called by muse, mutect2, varscan2
- HDX | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218172983, COSV52976198, COSV52983078; called by muse, mutect2, varscan2
- IGF1R | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 72/546 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs763660010; called by muse, mutect2, varscan2
- IGKV5-2 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs760586732; called by muse, mutect2, varscan2
- ITGB4 | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 137/587 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs754773105; called by muse, mutect2, varscan2
- KIF26B | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.366); catalogued as rs1280577981, COSV68572252; called by muse, mutect2, varscan2
- KRTAP5-3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 52/392 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs571662260, COSV101294499, COSV68790920; called by mutect2, varscan2
- LRRK2 | c.5203C>T p.R1735* | Nonsense Mutation (SNP) | VAF 40/274 reads (15%) | catalogued as rs1381739913, COSV100110597; called by muse, mutect2, varscan2
- MAP3K15 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs759649993; called by muse, mutect2, varscan2
- MYT1L | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs756426615, COSV67722361; called by muse, mutect2, varscan2
- MYT1L | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as rs1024589526; called by muse, mutect2, varscan2
- NADK | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1265614547; called by muse, mutect2, varscan2
- OR5D14 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs376987168, COSV59456133; called by muse, mutect2, varscan2
- PFKFB3 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 20/173 reads (12%) | PolyPhen probably damaging (1); catalogued as rs749129357; called by muse, mutect2, varscan2
- PLVAP | c.1239C>T p.I413= | Splice Region (SNP) | VAF 18/114 reads (16%) | catalogued as rs746916181; called by muse, mutect2, varscan2
- SALL1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 74/340 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1223836455, COSV51758197; called by muse, mutect2, varscan2
- SERPINB5 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs1303408352; called by muse, mutect2, varscan2
- SORCS3 | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63819708; called by muse, mutect2, varscan2
- SPATA31A1 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1160296659; called by mutect2, varscan2
- SPINK5 | c.3178C>T p.P1060S | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs749346981; called by muse, mutect2, varscan2
- SRPX | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 18/130 reads (14%) | catalogued as rs756523506; called by muse, mutect2, varscan2
- STKLD1 | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs35683622; called by muse, mutect2, varscan2
- ZNF674 | c.1022G>T p.C341F | Missense Mutation (SNP) | VAF 79/709 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV70378928; called by mutect2, varscan2
- ABCB9 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCE1 | c.710T>C p.I237T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ADAMTS12 | c.2293T>C p.Y765H | Missense Mutation (SNP) | VAF 53/404 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- AFF2 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- AGO4 | c.1006A>G p.I336V | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- APC | c.720del p.E241Kfs*52 | Frame Shift Del (DEL) | VAF 19/130 reads (15%) | called by mutect2, pindel, varscan2
- ARL6IP6 | c.329_330del p.S110Yfs*23 | Frame Shift Del (DEL) | VAF 30/179 reads (17%) | called by pindel, varscan2
- ATP7B | c.3283C>T p.Q1095* | Nonsense Mutation (SNP) | VAF 109/542 reads (20%) | called by muse, mutect2, varscan2
- BRWD3 | c.3576G>T p.R1192S | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CEP112 | c.1233A>T p.K411N | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- CFAP61 | c.3186del p.L1063Wfs*12 | Frame Shift Del (DEL) | VAF 41/350 reads (12%) | called by mutect2, pindel, varscan2
- CKAP5 | c.3421G>A p.G1141R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- CNKSR2 | c.1838_1839insC p.K613Nfs*7 | Frame Shift Ins (INS) | VAF 34/133 reads (26%) | called by pindel, varscan2
- CPS1 | c.2071T>G p.L691V | Missense Mutation (SNP) | VAF 73/539 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DDX24 | c.2014G>A p.V672I | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- DNAH5 | c.2320A>G p.I774V | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FOXD4L3 | c.890dup p.C298Vfs*90 | Frame Shift Ins (INS) | VAF 103/579 reads (18%) | called by mutect2, pindel, varscan2
- GOLGA6L17P | n.346G>T | Splice Region (SNP) | VAF 31/221 reads (14%) | called by muse, mutect2, varscan2
- GPATCH8 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY1A2 | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- H2BC3 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- HORMAD2 | c.181C>A p.R61S | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- HPS4 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 119/436 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- JADE3 | c.1115T>A p.L372H | Missense Mutation (SNP) | VAF 44/375 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- KCNQ5 | c.673_674insG p.I225Sfs*69 | Frame Shift Ins (INS) | VAF 21/118 reads (18%) | called by mutect2, pindel, varscan2
- KNTC1 | c.4930G>T p.E1644* | Nonsense Mutation (SNP) | VAF 64/246 reads (26%) | called by muse, mutect2, varscan2
- LILRB5 | c.657C>T p.G219= | Splice Region (SNP) | VAF 26/166 reads (16%) | called by muse, mutect2, varscan2
- ORC3 | c.1958C>A p.A653E | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); called by muse, mutect2
- PARP12 | c.1185C>T p.G395= | Splice Region (SNP) | VAF 22/132 reads (17%) | called by muse, mutect2, varscan2
- PCDHA1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by muse, mutect2
- PLCD1 | c.1268del p.N423Tfs*9 | Frame Shift Del (DEL) | VAF 115/444 reads (26%) | called by mutect2, pindel, varscan2
- PRDM2 | c.3136C>T p.P1046S | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- PREX2 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PTPRN2 | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- SEMA3F | c.1018+1G>T p.X340_splice | Splice Site (SNP) | VAF 19/157 reads (12%) | called by muse, mutect2, varscan2
- SH3D19 | c.1552T>G p.S518A | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- SLC24A5 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLC9A4 | c.1887C>G p.I629M | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- TBC1D5 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- THADA | c.3829A>G p.T1277A | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWF | c.1520G>A p.R507K | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- WDR49 | c.1288A>G p.K430E (on ENST00000308378 / NM_001366158.1; = p.K771E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF81 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- ACTN2 | c.2376C>T p.A792= | Silent (SNP) | VAF 98/331 reads (30%) | catalogued as rs369320952; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKRD34C | c.1137C>A p.L379= | Silent (SNP) | VAF 53/407 reads (13%) | catalogued as COSV69854221; called by muse, mutect2, varscan2
- BMX | c.588C>T p.N196= | Silent (SNP) | VAF 37/326 reads (11%) | catalogued as rs774649678; called by muse, mutect2, varscan2
- CACNA1G | c.4338C>T p.T1446= | Silent (SNP) | VAF 28/280 reads (10%) | catalogued as COSV61742367; called by muse, mutect2, varscan2
- CELSR3 | c.4893C>T p.S1631= | Silent (SNP) | VAF 35/268 reads (13%) | catalogued as rs774824972, COSV50958745, COSV51144015; called by muse, mutect2, varscan2
- DCC | c.3747C>T p.S1249= | Silent (SNP) | VAF 78/288 reads (27%) | catalogued as rs749095614, COSV71431094, COSV99081690; called by muse, mutect2, varscan2
- DISP3 | c.717C>T p.H239= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs1237130265; called by muse, mutect2, varscan2
- DSCAML1 | c.5283C>T p.G1761= (on ENST00000321322; = p.G1701= on NM_020693.4) | Silent (SNP) | VAF 20/170 reads (12%) | catalogued as rs1468914313, COSV58387492; called by muse, mutect2, varscan2
- ELFN1 | c.36C>T p.C12= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs747704550; called by muse, mutect2, varscan2
- MAP3K4 | c.3975T>G p.P1325= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as rs777012160; called by muse, mutect2
- MLLT10 | c.1122C>T p.F374= | Silent (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- MUC16 | c.7956C>A p.L2652= | Silent (SNP) | VAF 97/323 reads (30%) | called by muse, mutect2, varscan2
- NAV3 | c.2790A>G p.K930= | Silent (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- NOTCH3 | c.4479C>T p.C1493= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV54637533; called by muse, mutect2, varscan2
- PCDHA13 | c.1362G>A p.A454= | Silent (SNP) | VAF 42/464 reads (9%) | catalogued as rs1424400219, COSV56495765; called by muse, mutect2
- RYR3 | c.3732T>C p.F1244= | Silent (SNP) | VAF 47/388 reads (12%) | called by muse, mutect2, varscan2
- SAMD4B | c.225C>T p.S75= | Silent (SNP) | VAF 19/171 reads (11%) | called by muse, mutect2, varscan2
- SLC30A8 | c.468C>T p.G156= | Silent (SNP) | VAF 43/165 reads (26%) | catalogued as rs757129691, COSV69973343; called by muse, mutect2, varscan2
- STK11IP | c.237C>T p.F79= | Silent (SNP) | VAF 90/362 reads (25%) | catalogued as rs370813924; called by muse, mutect2, varscan2
- TACR3 | c.417G>C p.T139= | Silent (SNP) | VAF 78/470 reads (17%) | catalogued as COSV59210029; called by mutect2, varscan2
- TTN | c.53898A>G p.G17966= (on ENST00000591111; = p.G10542= on NM_003319.4) | Silent (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2, varscan2
- ZNF257 | c.762G>A p.E254= | Silent (SNP) | VAF 38/372 reads (10%) | catalogued as COSV71307170; called by muse, varscan2
- ZNF407 | c.6414C>T p.S2138= | Silent (SNP) | VAF 119/423 reads (28%) | catalogued as rs367785014; called by muse, mutect2, varscan2
- AC068587.7 | chr8:12659593 A>T | 5'Flank (SNP) | VAF 16/288 reads (6%) | catalogued as rs1182876539; called by muse, mutect2
- ACBD5 | chr10:27195985 C>T | 3'Flank (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- ACTN2 | c.698-1157A>C | Intron (SNP) | VAF 26/162 reads (16%) | called by muse, mutect2, varscan2
- AGAP7P | n.1898C>T | RNA (SNP) | VAF 36/464 reads (8%) | catalogued as rs1236800235; called by muse, mutect2
- BAALC-AS2 | n.169G>A | RNA (SNP) | VAF 42/182 reads (23%) | catalogued as rs572223402; called by muse, mutect2, varscan2
- FBXL3 | c.*1A>T | 3'UTR (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- GNLY | c.*108C>A | 3'UTR (SNP) | VAF 21/216 reads (10%) | catalogued as COSV99808837; called by muse, mutect2, varscan2
- GSDMD | c.1139-18del | Intron (DEL) | VAF 62/322 reads (19%) | called by mutect2, pindel, varscan2
- MAP2 | c.455-1999A>G | Intron (SNP) | VAF 54/213 reads (25%) | catalogued as rs1559564128; called by muse, mutect2, varscan2
- MAU2 | c.*218C>G | 3'UTR (SNP) | VAF 42/328 reads (13%) | called by muse, mutect2, varscan2
- MCRS1 | c.11-186G>C | Intron (SNP) | VAF 37/236 reads (16%) | called by muse, mutect2, varscan2
- MFRP | chr11:119344755 T>A | 5'Flank (SNP) | VAF 86/633 reads (14%) | called by muse, mutect2, varscan2
- MMGT1 | c.-41G>A | 5'UTR (SNP) | VAF 61/365 reads (17%) | called by muse, mutect2, varscan2
- MPRIP | c.2163+2902G>A | Intron (SNP) | VAF 70/221 reads (32%) | called by muse, mutect2, varscan2
- NEK7 | c.198+3229A>T | Intron (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- SLC25A13 | c.*791G>A | 3'UTR (SNP) | VAF 52/407 reads (13%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088189 G>A | 3'Flank (SNP) | VAF 32/285 reads (11%) | catalogued as rs751387895; called by muse, mutect2, varscan2
